TCGA case TCGA-E1-5307 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a6ee311c-0a7b-4f47-86f1-f2164b128f9c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Dead; Days to death: 1,762 days (4.8 years).

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,837 days); Year of diagnosis: 2000; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Altered Mental Status; Sites of involvement: Brain, Temporal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 91 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 126 days; Days to treatment end: 215 days; Number of cycles: 2; Treatment dose: 300 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 229 days; Days to treatment end: 260 days; Number of cycles: 1; Treatment dose: 1,250 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 260 days; Days to treatment end: 285 days; Number of cycles: 1; Treatment dose: 1,675 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 313 days; Days to treatment end: 351 days; Number of cycles: 1; Treatment dose: 180 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 382 days (1.0 years); Days to treatment end: 466 days (1.3 years); Number of cycles: 1; Treatment dose: 130 mg; Prescribed dose: 82.5; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 466 days (1.3 years); Days to treatment end: 560 days (1.5 years); Number of cycles: 3; Treatment dose: 3,750 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 560 days (1.5 years); Days to treatment end: 1,453 days (4.0 years); Number of cycles: 41; Treatment dose: 45,920 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,462 days (4.0 years); Days to treatment end: 1,599 days (4.4 years); Number of cycles: 4; Treatment dose: 4,800 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,599 days (4.4 years); Days to treatment end: 1,720 days (4.7 years); Number of cycles: 4; Treatment dose: 6,000 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 66.5 years (24,289 days); Days to diagnosis: 1,452 days (4.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Day 95 (prior to adjuvant therapy): Karnofsky performance status: 80.
- Day 1,452 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,762 days (4.8 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Altered Mental Status.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-5307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-E1-5307-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-E1-5307-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-E1-5307-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Temporal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: Yes; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; Related symptom first present: Mental Status Changes; First symptom longest duration: > 181 Days; History asthma: No; History eczema: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 8; Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 6; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 4: Regimen number: 5; Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 5: Regimen number: 1; Pharmaceutical therapy drug name: CCNu.
- Drug treatment 6: Regimen number: 4; Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 7: Regimen number: 3; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 8: Regimen number: 9; Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.
- Drug treatment 9: Regimen number: 7; Pharmaceutical therapy drug name: Celebrex.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; Performance status timing: Pre-Adjuvant Therapy; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,762 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,762 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,452 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-5307-01A-01D-1892-01): tumor purity 0.19, ploidy 3.75, whole-genome doublings 1.
